Somatic mutation profile of tumor specimen TCGA-V1-A9O7-01A (aliquot TCGA-V1-A9O7-01A-21D-A41K-08) from TCGA case TCGA-V1-A9O7, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9O7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2dabb49-b926-47b6-9d8d-6f08fa4e915e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9O7-10A (Blood Derived Normal), aliquot TCGA-V1-A9O7-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10d0626b-d520-444e-a97c-c4ec8512562f

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- XRCC2 | c.39+1G>A p.X13_splice | Splice Site (SNP) | VAF 7/43 reads (16%) | catalogued as rs560785131, COSV100831587; ClinVar: likely pathogenic; called by mutect2, varscan2
- ADGRB1 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs773821198, COSV100029353; called by muse, mutect2, varscan2
- CHD7 | c.5316G>T p.W1772C | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as CM123508, COSV101418067, COSV71114574; called by muse, mutect2
- DIP2C | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as COSV99793559; called by muse, mutect2, varscan2
- EHMT2 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs143327875; called by muse, mutect2, varscan2
- FMR1 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.394); catalogued as COSV54421945; called by muse, mutect2, varscan2
- GRIA1 | c.2612G>T p.G871V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.027); catalogued as COSV99598697; called by muse, mutect2, varscan2
- HOXB1 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs776614578, COSV99495367; called by muse, mutect2
- LPA | c.3437C>A p.P1146Q | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as rs1220890877, COSV60314118; called by muse, mutect2, varscan2
- LYN | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70205285; called by muse, mutect2
- NRXN3 | c.67T>A p.F23I | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as COSV99816818; called by muse, mutect2
- NT5C1B | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); catalogued as COSV100409889; called by muse, mutect2, varscan2
- PEX3 | c.265C>G p.L89V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV100852107; called by muse, mutect2
- PLCL1 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.285); catalogued as COSV101406831; called by muse, mutect2, varscan2
- RIMBP2 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99898745; called by muse, mutect2, varscan2
- RP1 | c.6212T>C p.L2071S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99606657; called by muse, mutect2
- UBTF | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV100255818; called by muse, mutect2, varscan2
- XAB2 | c.111C>G p.C37W | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.662); catalogued as COSV100222006; called by muse, mutect2, varscan2
- ATM | c.4187_4191del p.C1396* | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel
- GTF3C4 | c.522C>T p.C174= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as rs372437145; called by muse, mutect2
- IL3RA | c.894C>A p.G298= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100452216; called by muse, mutect2
- MRC1 | c.1908G>A p.P636= | Silent (SNP) | VAF 8/143 reads (6%) | catalogued as rs781948465; called by muse, mutect2
- PMPCB | c.561C>T p.T187= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99971146; called by muse, mutect2, varscan2
- TAAR2 | c.342A>G p.T114= (on ENST00000367931 / NM_001033080.1; = p.T69= on NM_014626.3) | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs762896741, COSV99255565; called by muse, mutect2, varscan2
- USP31 | c.2832C>T p.V944= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV99564805; called by muse, mutect2
- HEXD | c.*175A>T | 3'UTR (SNP) | VAF 12/124 reads (10%) | catalogued as COSV100027618; called by muse, mutect2, varscan2
